Surgical pathology report (de-identified scan), TCGA case TCGA-62-8399, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Thoraxklinik at University Hospital Heidelberg, specimen TCGA-62-8399-01A (Primary Tumor).

TSS Name: [REDACTED]

TSS Identifier: [REDACTED]

TSS Unique Patient #: [REDACTED]

Pathology Report-Summary:

Material:

lung, left, upper lobe: 19.0 x 11.0 x 7.0 cm

tumor: 4.0 x 3.0 x 5.0 cm

Diagnosis:

Adenocarcinoma, mostly papillary, partially acinar

pT2, pN2 (7/30), pMx, G2

Pathologist: [REDACTED]

[REDACTED]

Date:

Source: NCI Genomic Data Commons file d6768b43-92fd-48ba-80ed-c16df6fdc643 (TCGA-62-8399.10C88394-5444-48A1-BE79-56733264D087.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).